Somatic mutation profile of tumor specimen BA2731D (aliquot aq-BA2731D) from BEATAML1.0 case 2036, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,351 days).
Specimen BA2731D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67defaee-29b2-41b0-9039-6a3ed4cf19f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2048D (Solid Tissue Normal), aliquot aq-BA2048D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96564ac7-c546-4b92-992c-1d3a77f3cc04

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs141449825; called by muse, mutect2, varscan2
- LINC02692 | n.485+1G>T | Splice Site (SNP) | VAF 29/64 reads (45%) | catalogued as rs1163830032; called by muse, mutect2, varscan2
- SIGLEC9 | c.845del p.P282Lfs*4 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs1568612003, COSV51586901; called by mutect2, pindel, varscan2
- SLTM | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99989402; called by muse, mutect2
- TRANK1 | c.3923C>G p.S1308C | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448987598, COSV57147290; called by muse, mutect2, varscan2
- TRIL | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs930468179; called by muse, mutect2
- CEBPA | c.1012_1016dup p.G340Cfs*84 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, varscan2
- NRXN3 | c.1027C>A p.H343N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- PRKCE | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIRPB2 | c.25A>C p.T9P | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A7 | c.1489-1G>C p.X497_splice | Splice Site (SNP) | VAF 127/273 reads (47%) | called by muse, mutect2, varscan2
- IGSF9B | c.3348C>T p.P1116= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- KCNK6 | c.372C>A p.I124= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- RYR1 | c.7698G>A p.A2566= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV62098573; called by muse, mutect2, varscan2
- SATB2 | c.1887C>T p.L629= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as COSV53479846, COSV53492784; called by muse, mutect2, varscan2
